Somatic mutation profile of tumor specimen TCGA-04-1343-01A (aliquot TCGA-04-1343-01A-01W-0486-08) from TCGA case TCGA-04-1343, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.4 years (26,428 days).
Specimen TCGA-04-1343-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8514090e-a327-4e1d-8225-1f219518718e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1343-10A (Blood Derived Normal), aliquot TCGA-04-1343-10A-01W-0487-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/184d066a-942b-47e9-8ab7-d570ad2c7b0a

The open-access MAF lists 84 somatic variants for this specimen: 54 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 29, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC136428.1 | c.112A>G p.R38G | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV71169304; called by muse, mutect2, varscan2
- ADCY3 | c.1281G>T p.Q427H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53167392, COSV99567751; called by muse, mutect2, varscan2
- AKAP9 | c.11505C>A p.D3835E (on ENST00000359028; = p.D3811E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.275); catalogued as COSV99133616; called by muse, mutect2
- ANO8 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as COSV99344105; called by muse, mutect2, varscan2
- ARID2 | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 150/342 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV57616234; called by muse, mutect2, varscan2
- ATG9A | c.1635C>A p.Y545* | Nonsense Mutation (SNP) | VAF 7/102 reads (7%) | catalogued as COSV99521583; called by muse, mutect2
- BOD1 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53633370; called by muse, mutect2, varscan2
- CCDC180 | c.1248+1G>C p.X416_splice | Splice Site (SNP) | VAF 28/78 reads (36%) | catalogued as COSV63836183; called by muse, mutect2
- CCDC61 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs754811809, COSV54430587; called by muse, mutect2, varscan2
- CDK15 | c.781G>A p.V261M (on ENST00000652192 / NM_001366386.2; = p.V210M on NM_139158.2) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755877050, COSV53636913, COSV53637977; called by muse, mutect2, varscan2
- CELF4 | c.86G>C p.S29T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58446890, COSV58467921; called by muse, mutect2
- DGKD | c.2564dup p.T856Yfs*5 (on ENST00000264057 / NM_152879.3; = p.T812Yfs*5 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/70 reads (17%) | catalogued as rs35538077; called by mutect2, varscan2
- DMXL2 | c.2345T>C p.F782S | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51857778; called by muse, mutect2, varscan2
- DNAH2 | c.7117C>G p.L2373V | Missense Mutation (SNP) | VAF 119/572 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.171); catalogued as COSV66728389; called by muse, mutect2, varscan2
- DOCK3 | c.3554C>A p.T1185N | Missense Mutation (SNP) | VAF 245/340 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.334); catalogued as COSV56553577; called by muse, mutect2, varscan2
- DUSP1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53321312; called by muse, mutect2
- EOMES | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 117/161 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1473312287, COSV55416020; called by muse, mutect2, varscan2
- FARS2 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV99212910; called by mutect2, varscan2
- FLG | c.9454T>A p.S3152T | Missense Mutation (SNP) | VAF 93/755 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as COSV100910619; called by muse, mutect2, varscan2
- GRIA4 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.091); catalogued as COSV56922885; called by muse, mutect2, varscan2
- HDAC4 | c.2848G>A p.A950T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs753247137, COSV100612746; called by muse, mutect2, varscan2
- IL12RB2 | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV52027931; called by muse, mutect2, varscan2
- INPPL1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs774794017, COSV53352894; called by muse, mutect2, varscan2
- ITGA8 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV65237249; called by muse, mutect2
- KCNH2 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as COSV100059256; called by muse, mutect2, varscan2
- KIAA1210 | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 244/510 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV68180629, COSV68181153; called by muse, mutect2, varscan2
- LRP1B | c.8809G>A p.G2937R | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67275037, COSV67281194; called by muse, mutect2
- LRP2 | c.9128G>A p.R3043H | Missense Mutation (SNP) | VAF 86/339 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as rs143078432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPL53 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs866496733, COSV50688595; called by muse, mutect2
- NGEF | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50921135, COSV50963847; called by muse, mutect2, varscan2
- NLRP13 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as COSV100738055; called by muse, mutect2
- OCA2 | c.2341A>T p.N781Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100667011; called by muse, mutect2, varscan2
- OLFM3 | c.454G>C p.E152Q (on ENST00000338858 / NM_001288821.1; = p.E132Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.132); catalogued as COSV58805324; called by muse, mutect2, varscan2
- OR2T6 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63217159; called by muse, mutect2, varscan2
- PCDHGA5 | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 13/101 reads (13%) | catalogued as rs561614642, COSV53977221; called by muse, mutect2, varscan2
- PRR5L | c.266T>A p.L89H | Missense Mutation (SNP) | VAF 110/936 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61123870; called by muse, varscan2
- RAB3C | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 65/442 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV51443194; called by muse, mutect2, varscan2
- RREB1 | c.4615C>G p.P1539A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58566807; called by muse, mutect2, varscan2
- SCN3A | c.2156T>A p.L719H | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51826623; called by muse, mutect2, varscan2
- SEZ6L | c.2212+1G>A p.X738_splice | Splice Site (SNP) | VAF 75/179 reads (42%) | catalogued as COSV50683612; called by muse, mutect2, varscan2
- SLC26A6 | c.1783_1785del p.E595del | In Frame Del (DEL) | VAF 67/302 reads (22%) | catalogued as rs780427143; called by pindel, varscan2
- SOCS5 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60603916, COSV60604974; called by muse, mutect2, varscan2
- SUPT5H | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 42/369 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV63242533; called by muse, mutect2, varscan2
- TAF1 | c.1817G>A p.G606D (on ENST00000373790 / NM_138923.4; = p.G627D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52127308; called by muse, mutect2, varscan2
- TIAM1 | c.1627C>T p.H543Y | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99733111; called by muse, mutect2
- TP53 | c.625_629del p.R209Hfs*5 | Frame Shift Del (DEL) | VAF 167/232 reads (72%) | catalogued as COSV53718936; called by mutect2, pindel, varscan2
- TTN | c.8923C>G p.L2975V (on ENST00000591111; = p.L2929V on NM_003319.4) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | PolyPhen possibly damaging (0.814); catalogued as COSV100630695, COSV60391208; called by muse, mutect2, varscan2
- TYW3 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV61718870; called by muse, varscan2
- UBAP2 | c.2159C>T p.S720L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs144480091; called by muse, mutect2, varscan2
- WNK4 | c.1822dup p.V608Gfs*7 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | catalogued as rs762079039; called by mutect2, varscan2
- ZBTB20 | c.1507G>T p.A503S (on ENST00000474710 / NM_001164342.2; = p.A430S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV61872464; called by muse, mutect2
- ZBTB22 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV56473339; called by muse, mutect2, varscan2
- GRIA3 | c.253del p.S85Pfs*2 | Frame Shift Del (DEL) | VAF 138/313 reads (44%) | called by mutect2, pindel, varscan2
- PCOLCE | c.446_449del p.R149Pfs*21 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by pindel, varscan2
- AGRN | c.252C>T p.S84= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV101038617; called by muse, mutect2
- AHNAK2 | c.5481G>A p.K1827= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as rs775069404, COSV100319021, COSV60907622; called by muse, mutect2, varscan2
- B3GALT4 | c.651G>A p.L217= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV101005557; called by muse, mutect2
- CD99L2 | c.363G>A p.L121= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as COSV100692012; called by muse, mutect2, varscan2
- CHST15 | c.909G>A p.G303= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs1463244014, COSV100654945; called by muse, mutect2, varscan2
- CLIP1 | c.2481G>T p.G827= (on ENST00000620786 / NM_001247997.1; = p.G816= on NM_002956.2) | Silent (SNP) | VAF 62/246 reads (25%) | catalogued as rs772841127, COSV56809562; called by muse, mutect2, varscan2
- CSMD1 | c.1620G>C p.T540= (on ENST00000520002; = p.T539= on NM_033225.6) | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs185713105, COSV59393584; called by muse, mutect2, varscan2
- CSTB | c.144C>T p.V48= | Silent (SNP) | VAF 12/153 reads (8%) | catalogued as rs202096395, COSV99376897; called by muse, mutect2
- DPYD | c.1386A>C p.P462= | Silent (SNP) | VAF 32/164 reads (20%) | catalogued as COSV64595011, COSV64596911, COSV64617212; called by muse, mutect2, varscan2
- DSCAML1 | c.525C>T p.P175= (on ENST00000321322; = p.P115= on NM_020693.4) | Silent (SNP) | VAF 13/193 reads (7%) | catalogued as COSV100354803; called by muse, mutect2
- GIMAP8 | c.1677C>T p.Y559= | Silent (SNP) | VAF 22/334 reads (7%) | catalogued as COSV56231721; called by muse, mutect2
- GSTA2 | c.216C>G p.L72= | Silent (SNP) | VAF 98/1117 reads (9%) | catalogued as COSV101534030; called by muse, mutect2
- IL13RA2 | c.582T>C p.N194= | Silent (SNP) | VAF 66/167 reads (40%) | catalogued as COSV54567886; called by muse, mutect2, varscan2
- INTS4 | c.552C>G p.V184= | Silent (SNP) | VAF 125/485 reads (26%) | catalogued as COSV71093131, COSV71093705; called by muse, mutect2, varscan2
- ITPR1 | c.5760C>A p.S1920= (on ENST00000354582; = p.S1865= on NM_002222.7) | Silent (SNP) | VAF 15/163 reads (9%) | catalogued as COSV100229813; called by muse, mutect2
- MAGEB1 | c.717G>T p.G239= | Silent (SNP) | VAF 8/177 reads (5%) | catalogued as rs1305138383, COSV100974856; called by muse, mutect2
- MYH1 | c.4482A>G p.E1494= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV56858298; called by muse, mutect2, varscan2
- NADK2 | c.684G>A p.G228= (on ENST00000381937 / NM_001085411.3; = p.G65= on NM_153013.4) | Silent (SNP) | VAF 29/179 reads (16%) | catalogued as COSV56939902; called by muse, mutect2, varscan2
- PPARGC1A | c.1923G>A p.Q641= | Silent (SNP) | VAF 22/620 reads (4%) | catalogued as COSV99337307; called by muse, mutect2
- PREP | c.1248C>T p.P416= (on ENST00000369110; = p.P482= on NM_002726.5) | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV64872549; called by muse, mutect2, varscan2
- RRBP1 | c.3219A>G p.E1073= (on ENST00000377813 / NM_001365613.2; = p.E640= on NM_004587.3) | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs1235147969, COSV55709539; called by muse, mutect2, varscan2
- SCN8A | c.2676G>A p.V892= | Silent (SNP) | VAF 16/271 reads (6%) | catalogued as COSV100633345, COSV61984732; called by muse, mutect2
- SLC36A3 | c.366C>T p.C122= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as rs1428332460, COSV100077390; called by muse, mutect2
- SYT9 | c.1209G>T p.L403= | Silent (SNP) | VAF 41/416 reads (10%) | catalogued as COSV59626122; called by muse, mutect2
- TEAD2 | c.249C>T p.I83= | Silent (SNP) | VAF 26/265 reads (10%) | catalogued as rs746445822, COSV55563278; called by muse, mutect2
- TUBB | c.420C>T p.G140= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs773923877, COSV58357535; called by muse, mutect2
- USP31 | c.3294G>A p.E1098= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV54858163; called by muse, mutect2
- Z83844.2 | c.1590C>T p.C530= | Silent (SNP) | VAF 86/175 reads (49%) | catalogued as COSV53217613; called by muse, mutect2, varscan2
- ZNF816 | c.1110G>A p.K370= | Silent (SNP) | VAF 16/500 reads (3%) | catalogued as COSV99554461; called by muse, mutect2
- CIT | c.2082+1912G>A | Intron (SNP) | VAF 114/294 reads (39%) | catalogued as rs762975110, COSV55866306; called by muse, mutect2, varscan2
